Gene-level copy-number profile of tumor specimen TCGA-PE-A5DC-01A from TCGA case TCGA-PE-A5DC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.6 years (26,514 days).
Specimen TCGA-PE-A5DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.c5b1d103-453a-4fe5-aef2-63683a56d262.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PE-A5DC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/57946d7c-737c-4adf-9b2c-a0668bb29673

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 194; copy number 1: 6; copy number 2: 13,818; copy number 3: 311; copy number 4: 39,574; copy number 5: 949; copy number 6: 3,995; copy number 7: 26; copy number 8: 70; copy number 9: 752; copy number 12: 78; copy number 13: 47.

Homozygous deletions (total copy number 0; autosomes only): 194 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,201,469–27,297,150, 86 genes (broad region; genes not listed).
- chr9:27,391,734–27,397,563, 1 gene: AL163192.1.
- chr13:18,467,172–20,567,045, 70 genes (broad region; genes not listed).
- chr13:31,419,989–33,350,630, 28 genes (within-gene range 0–2): AL161616.2, AL161616.1, RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1.
- chr16:55,984,009–56,357,444, 9 genes (within-gene range 0–2): AC040168.1, AC040168.2, AC007495.1, GNAO1, DKFZP434H168, MIR3935, AC009102.4, AC009102.1, AC009102.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 877 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:97,868,840–145,066,685, 752 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr11:68,980,021–70,436,584, 47 genes, copy number 13: MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:72,223,701–74,398,433, 76 genes, copy number 12 (broad region; genes not listed).
- chr11:74,398,825–74,416,379, 2 genes, copy number 12: AP001085.1, MIR548AL.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
